Somatic mutation profile of tumor specimen 0DSBYH from CCDI case PBCHVV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.7 years (6,082 days).
Specimen 0DSBYH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b7e711a-e825-41c9-9d57-cbaff3d51bfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSBY8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c84f7803-ea4d-470b-9544-c73602802be5

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Nonsense Mutation 5, Intron 2, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL17A1 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 152/362 reads (42%) | catalogued as rs775196743, CM031149; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/254 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 85/233 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 145/170 reads (85%) | catalogued as rs397514641, CM000774, COSV62197492; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATRX | c.2422C>T p.R808* | Nonsense Mutation (SNP) | VAF 201/431 reads (47%) | catalogued as COSV64874953; called by muse, mutect2, varscan2
- CDH9 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 524/797 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755843215, COSV50260964; called by muse, mutect2, varscan2
- GAL3ST1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 129/341 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.767); catalogued as rs1398726436, COSV100143239; called by muse, mutect2, varscan2
- GLA | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 142/329 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as CM012768; called by muse, mutect2, varscan2
- IFFO2 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 168/405 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs977309634; called by muse, mutect2, varscan2
- NYAP2 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.165); catalogued as rs1425272563; called by muse, mutect2, varscan2
- PAPPA2 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 238/541 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); catalogued as rs758781900, COSV62773172; called by muse, mutect2, varscan2
- PPM1D | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 190/442 reads (43%) | catalogued as rs1315208220, COSV100010508, COSV59958163; called by muse, mutect2, varscan2
- QRICH2 | c.224T>C p.M75T | Missense Mutation (SNP) | VAF 176/380 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377406030; called by muse, mutect2, varscan2
- RBMXL3 | c.2656T>C p.Y886H | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1569516069; called by muse, mutect2, varscan2
- RBP3 | c.1723C>T p.H575Y | Missense Mutation (SNP) | VAF 97/223 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs782379329; called by muse, mutect2, varscan2
- SIGLEC11 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 139/310 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as rs768999708, COSV101389515; called by muse, mutect2, varscan2
- TLR8 | c.1354C>T p.R452W (on ENST00000218032 / NM_138636.5; = p.R470W on NM_016610.4) | Missense Mutation (SNP) | VAF 221/543 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.216); catalogued as rs1218810960; called by muse, mutect2, varscan2
- DIO3 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 87/185 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK4 | c.3046A>T p.N1016Y | Missense Mutation (SNP) | VAF 131/324 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- RASGRP3 | c.1481T>C p.I494T (on ENST00000402538 / NM_001349975.2; = p.I493T on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/440 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.042); called by muse, mutect2
- SMIM21 | c.278C>A p.S93* | Nonsense Mutation (SNP) | VAF 61/146 reads (42%) | called by muse, mutect2, varscan2
- CTAG2 | c.390C>T p.G130= | Silent (SNP) | VAF 151/337 reads (45%) | catalogued as rs1557241476; called by muse, mutect2, varscan2
- LCT | c.4761C>T p.R1587= | Silent (SNP) | VAF 134/324 reads (41%) | catalogued as rs573401319, COSV51545280, COSV51552658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPANXN3 | c.-43T>C | 5'UTR (SNP) | VAF 52/158 reads (33%) | called by muse, mutect2, varscan2
- STMND1 | c.412-74T>C | Intron (SNP) | VAF 36/86 reads (42%) | catalogued as rs1264911137; called by muse, mutect2, varscan2
- TMEM59 | c.391-69G>T | Intron (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
